Somatic mutation profile of tumor specimen TCGA-ET-A25J-01A (aliquot TCGA-ET-A25J-01A-11D-A16O-08) from TCGA case TCGA-ET-A25J, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 40.6 years (14,843 days).
Specimen TCGA-ET-A25J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fcc1d7f2-bfa8-4584-8154-87e7f9bef9a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A25J-11A (Solid Tissue Normal), aliquot TCGA-ET-A25J-11A-01D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fe50dd5-ee7f-49d7-905f-1a8fbd12afbe

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BICRAL | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 32/81 reads (40%) | catalogued as COSV58404439; called by muse, mutect2, varscan2
- CD101 | c.2810C>T p.T937M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs367547701; called by mutect2, varscan2
- CEP350 | c.7567A>G p.K2523E | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV62600229; called by muse, mutect2, varscan2
- GTDC1 | c.1329T>A p.H443Q (on ENST00000344850 / NM_001354361.1; = p.H358Q on NM_024659.6 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.125); catalogued as COSV53991179; called by muse, mutect2, varscan2
- MAP3K19 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as rs751721304, COSV59637434; called by muse, mutect2, varscan2
- SLC6A3 | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); catalogued as COSV54362798; called by muse, mutect2
- SHQ1 | c.399C>G p.P133= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs376103451, COSV57764649; called by muse, mutect2, varscan2
